Somatic mutation profile of tumor specimen C3N-00828-04 (aliquot CPT0013130009) from CPTAC case C3N-00828, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.0 years (24,489 days).
Specimen C3N-00828-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45664f5f-e3ab-44ce-b182-be242f6c45da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00828-31 (Blood Derived Normal), aliquot CPT0013200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db2d1903-a879-4c85-a394-9fd396615cb9

The open-access MAF lists 372 somatic variants for this specimen: 254 protein-altering or splice-affecting, 78 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 78, Intron 25, Nonsense Mutation 22, Frame Shift Del 7, 5'Flank 5, RNA 5, Splice Site 5, Splice Region 4, 3'UTR 3, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF3 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761573352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>G p.R479G (on ENST00000281708 / NM_001349798.2; = p.R399G on NM_018315.5) | Missense Mutation (SNP) | VAF 34/191 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747241612, COSV55894141, COSV55894999, COSV55908957; ClinVar: likely pathogenic; called by muse, mutect2
- NSD1 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs587784076, CM030069, COSV61776305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV53967959; called by muse, mutect2, varscan2
- ACSS3 | c.1201C>G p.R401G | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99699223; called by muse, mutect2, varscan2
- ADAM33 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241759274; called by muse, mutect2
- ADGRD1 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs1160997194; called by muse, mutect2, varscan2
- ADIPOQ | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs1560109934; called by muse, mutect2
- ADRA1D | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs1387764015; called by muse, mutect2, varscan2
- ALDH8A1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55641140; called by muse, mutect2, varscan2
- ALOXE3 | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 67/699 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.566); catalogued as COSV58554543; called by muse, mutect2
- ANKRD30A | c.313G>A p.E105K (on ENST00000611781; = p.E49K on NM_052997.2) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200651327; called by muse, mutect2, varscan2
- ANTKMT | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs757564119, COSV53497976; called by muse, mutect2, varscan2
- AOC1 | c.957C>G p.Y319* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | catalogued as rs565010501, COSV62870648, COSV62871134; called by muse, mutect2
- ARHGAP31 | c.3933G>A p.M1311I | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1371912382; called by muse, mutect2
- ASRGL1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs200906420, COSV57126022; called by muse, mutect2
- ATXN7L2 | c.562C>G p.P188A | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV63992976; called by muse, mutect2
- C2orf16 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs1277648447; called by muse, mutect2, varscan2
- CDH9 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs200287957, COSV50555710; called by muse, mutect2, varscan2
- CFAP69 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60184567; called by muse, mutect2, varscan2
- CFAP99 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 82/428 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs898555505; called by muse, mutect2, varscan2
- CRP | c.81T>G p.F27L | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as rs1275534045; called by muse, mutect2
- CYLD | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV61096956; called by muse, mutect2, varscan2
- DHX32 | c.1543+3A>G | Splice Region (SNP) | VAF 55/225 reads (24%) | catalogued as COSV52944086; called by muse, mutect2, varscan2
- DMWD | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs202210183, COSV52175033; called by muse, mutect2, varscan2
- DNAAF3 | c.243G>T p.E81D (on ENST00000524407 / NM_001256715.2; = p.E128D on NM_178837.4) | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66993063; called by muse, mutect2
- DNAH17 | c.12505G>A p.E4169K | Missense Mutation (SNP) | VAF 84/585 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs140459448; called by muse, mutect2, varscan2
- DNAH5 | c.11129G>T p.R3710L | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54224805; called by muse, mutect2, varscan2
- DNAH5 | c.10705G>T p.D3569Y | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54224439; called by muse, mutect2, varscan2
- DTNA | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 36/586 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs773504046, COSV51990798; called by muse, mutect2
- DUOX2 | c.1646A>G p.N549S | Missense Mutation (SNP) | VAF 218/740 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as rs368379567; called by muse, mutect2, varscan2
- EHMT1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 123/304 reads (40%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV58378091; called by muse, mutect2, varscan2
- FCAMR | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 110/342 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs751387228; called by muse, mutect2, varscan2
- FCRL3 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV100943549; called by muse, mutect2, varscan2
- FERD3L | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763167, COSV99284669; called by muse, mutect2
- GNB4 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as COSV51708706; called by muse, mutect2, varscan2
- HCN1 | c.2556del p.N853Tfs*23 | Frame Shift Del (DEL) | VAF 80/320 reads (25%) | catalogued as COSV57493376; called by mutect2, varscan2
- HCN1 | c.2555del p.P852Rfs*24 | Frame Shift Del (DEL) | VAF 105/402 reads (26%) | catalogued as COSV57528767; called by mutect2*, pindel, varscan2*
- IL17RC | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 30/616 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55970604; called by muse, mutect2
- INPP5D | c.1301C>A p.T434K (on ENST00000445964 / NM_001017915.3; = p.T433K on NM_005541.5) | Missense Mutation (SNP) | VAF 122/468 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV64039767; called by muse, mutect2, varscan2
- ITPRID1 | c.614T>A p.L205Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100086695; called by muse, varscan2
- KMT2A | c.11283C>A p.H3761Q | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV63286230; called by muse, mutect2, varscan2
- LMTK2 | c.3784G>C p.E1262Q | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51995071; called by muse, mutect2, varscan2
- LRRTM4 | c.1731G>T p.R577S | Missense Mutation (SNP) | VAF 81/431 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV69175207; called by muse, mutect2, varscan2
- MAP3K4 | c.2218A>T p.I740L | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62340099; called by muse, mutect2, varscan2
- MAPK6 | c.587G>C p.W196S | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55930212; called by muse, mutect2
- MCOLN2 | c.1673G>A p.S558N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.17); catalogued as rs1171048209; called by muse, mutect2, varscan2
- NDN | c.69C>A p.H23Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV59360882; called by muse, mutect2, varscan2
- NRXN3 | c.2839C>G p.R947G (on ENST00000335750 / NM_001330195.2; = p.R574G on NM_004796.6) | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV100205197; called by muse, mutect2, varscan2
- NWD2 | c.2800G>C p.E934Q | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs1487088497; called by muse, mutect2
- PCLO | c.5900G>T p.G1967V | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100431968; called by muse, mutect2
- PDE10A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV63108627; called by muse, mutect2
- PDE4DIP | c.4542G>C p.E1514D | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781787673; called by muse, mutect2, varscan2
- PHLDA1 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 77/384 reads (20%) | catalogued as COSV56997356; called by muse, varscan2
- PI15 | c.5T>C p.I2T | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs531766347; called by muse, mutect2, varscan2
- PLEKHA1 | c.1095A>T p.E365D | Missense Mutation (SNP) | VAF 98/482 reads (20%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1011327649; called by muse, mutect2, varscan2
- PNLIP | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV65042392; called by muse, mutect2, varscan2
- PRSS16 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs750160856, COSV57916082; called by muse, mutect2, varscan2
- PTPRD | c.5671G>T p.D1891Y | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61926952; called by muse, mutect2, varscan2
- RGS10 | c.236A>C p.Q79P (on ENST00000369101; = p.Q73P on NM_002925.3) | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as rs1441685962; called by muse, mutect2, varscan2
- RGS7 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58542153; called by muse, mutect2, varscan2
- RSRP1 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 11/182 reads (6%) | catalogued as COSV54562477; called by muse, mutect2
- RYR2 | c.12692C>T p.P4231L | Missense Mutation (SNP) | VAF 136/566 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1321340277, COSV63695745; called by muse, mutect2, varscan2
- SC5D | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs1463404277; called by muse, mutect2, varscan2
- SFRP2 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.069); catalogued as rs144480119; called by muse, mutect2, varscan2
- SGO2 | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.028); catalogued as rs868590855; called by muse, mutect2
- SNX4 | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs759810174; called by muse, mutect2
- SOGA3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 97/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64106260; called by muse, mutect2, varscan2
- SORCS3 | c.3338-2A>G p.X1113_splice | Splice Site (SNP) | VAF 16/172 reads (9%) | catalogued as rs760141602; called by muse, mutect2
- STAT5A | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV61806228, COSV61808008; called by muse, mutect2
- SYT4 | c.1239G>T p.R413S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99673858; called by muse, mutect2
- TEKT4 | c.880C>A p.R294S | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99726808; called by muse, mutect2
- TLL2 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs756485850; called by muse, mutect2, varscan2
- TMC8 | c.2081C>G p.S694C | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV59209373; called by muse, mutect2, varscan2
- TNRC18 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 31/344 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV101269637; called by muse, mutect2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 293/763 reads (38%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, mutect2, varscan2
- TSHZ1 | c.1883C>T p.T628M (on ENST00000580243 / NM_001308210.2; = p.T583M on NM_005786.6) | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs148468723, COSV59012409; called by muse, mutect2
- TTN | c.4444G>T p.G1482C (on ENST00000591111; = p.G1436C on NM_003319.4) | Missense Mutation (SNP) | VAF 24/201 reads (12%) | PolyPhen probably damaging (0.984); catalogued as COSV60282319; called by muse, mutect2, varscan2
- UGT1A5 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 127/442 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291086898, COSV100529843; called by muse, mutect2, varscan2
- UNC13B | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 176/384 reads (46%) | catalogued as COSV99059327; called by muse, mutect2, varscan2
- VCAM1 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV54118310; called by muse, mutect2
- ZNF225 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); catalogued as rs773356388; called by muse, mutect2, varscan2
- ACSBG2 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ACTR3B | c.1149G>T p.M383I | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ADAM20 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB3 | c.2107+1G>A p.X703_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- AGO3 | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AMZ2 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.188); called by muse, mutect2
- ARHGEF4 | c.1145A>T p.H382L | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN2 | c.1443T>A p.S481R (on ENST00000313400 / NM_001365069.1; = p.S430R on NM_014010.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ATP10A | c.3531C>G p.D1177E | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- C22orf42 | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- C6orf118 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.019); called by muse, mutect2
- CCDC151 | c.1466A>C p.D489A | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CCDC178 | c.2474A>G p.N825S (on ENST00000383096 / NM_001105528.3; = p.N787S on NM_198995.3) | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- CELF5 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEP192 | c.7328A>C p.E2443A | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2
- CHIT1 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 118/405 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CHPF | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.077); called by muse, mutect2
- CKAP2L | c.242G>T p.R81I | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CLDND1 | c.405_419del p.Y135_Q140delins* | Nonsense Mutation (DEL) | VAF 68/263 reads (26%) | called by mutect2, pindel, varscan2
- CNOT11 | c.716G>C p.S239T | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2
- COG6 | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 57/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL4A5 | c.4478A>C p.Q1493P | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.7169T>G p.L2390W (on ENST00000312481; = p.L2386W on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPEB2 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated, low confidence (0.2); called by muse, mutect2
- CRYBG2 | c.1994_1996del p.V665_Q666delinsE | In Frame Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- CSNK1G2 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CSNK1G2 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP2D7 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 15/476 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- DCAF4L1 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- DCBLD2 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 45/604 reads (7%) | called by muse, mutect2
- DHCR24 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 87/617 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DLG5 | c.4732G>A p.V1578M | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- DSCAM | c.3208G>A p.A1070T | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- DTL | c.1427C>A p.A476D | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DUSP14 | c.475dup p.I159Nfs*14 | Frame Shift Ins (INS) | VAF 42/412 reads (10%) | called by mutect2, pindel
- ECM2 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 115/372 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDRF1 | c.1186A>G p.T396A (on ENST00000356792 / NM_001202438.2; = p.T362A on NM_015608.2) | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- EML2 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 66/487 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- EPG5 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ESRP1 | c.1492G>C p.A498P | Missense Mutation (SNP) | VAF 17/524 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2
- ESRRG | c.1146A>G p.I382M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAAP20 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM169A | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM47B | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, varscan2
- FOXD4L5 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 50/244 reads (20%) | called by mutect2, varscan2
- FPGT | c.580A>T p.I194F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2
- GCKR | c.854T>A p.I285N | Missense Mutation (SNP) | VAF 37/588 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.119); called by muse, mutect2
- GFRA1 | c.1354del p.V452* | Frame Shift Del (DEL) | VAF 88/516 reads (17%) | called by mutect2, pindel, varscan2
- GLB1L2 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPC4 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- GPR6 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 78/417 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GRM6 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- H4C5 | c.103A>C p.I35L | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HDAC2 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HES3 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- HFM1 | c.3388A>T p.K1130* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2
- HHLA2 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2
- HOXA10 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 56/653 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.746); called by muse, mutect2
- HRH2 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV1-45 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 77/428 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- IMPG2 | c.1130C>G p.P377R | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- INHBA | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.028); called by muse, mutect2
- INSYN2A | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRX6 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAG2 | c.656del p.G219Afs*90 | Frame Shift Del (DEL) | VAF 210/1134 reads (19%) | called by mutect2, pindel, varscan2
- JPH2 | c.1825C>T p.L609F | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KCNN3 | c.493C>G p.R165G | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KEAP1 | c.221A>C p.Q74P | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- KLHL1 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2
- KLHL25 | c.913T>G p.F305V | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KRT79 | c.1430G>T p.C477F | Missense Mutation (SNP) | VAF 89/454 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LRRC37A3 | c.3158A>G p.N1053S | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- LSAMP | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MAPK15 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MARCHF1 | c.367T>A p.C123S (on ENST00000274056; = p.C106S on NM_017923.4) | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGA | c.4739del p.P1580Lfs*14 | Frame Shift Del (DEL) | VAF 95/303 reads (31%) | called by mutect2, pindel, varscan2
- MIA3 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 76/261 reads (29%) | called by muse, mutect2, varscan2
- MN1 | c.316C>G p.H106D | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.415); called by muse, mutect2
- MTMR7 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MUC17 | c.3748G>T p.V1250L | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- MUC19 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2
- MUC3A | c.7705del p.S2569Vfs*16 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- MYADM | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- MYCT1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH14 | c.1739C>G p.P580R | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- MYO10 | c.3317G>A p.S1106N | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2
- NBAS | c.6341G>T p.G2114V | Missense Mutation (SNP) | VAF 49/446 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- NDN | c.68A>G p.H23R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NF1 | c.4111-5T>C | Splice Region (SNP) | VAF 69/248 reads (28%) | called by muse, mutect2, varscan2
- NINL | c.1360G>T p.V454L | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NIPBL | c.6488G>A p.G2163D | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOTCH1 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 422/842 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOX3 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- NPAS2 | c.1673C>A p.T558N | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NPHS1 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 51/703 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NRSN1 | c.164del p.N55Tfs*19 | Frame Shift Del (DEL) | VAF 46/194 reads (24%) | called by mutect2, pindel, varscan2
- NTRK1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 116/405 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- OR10T2 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4N5 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 64/290 reads (22%) | called by muse, mutect2, varscan2
- OR51F1 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- OR5AS1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- OR5T3 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- OTOG | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 52/313 reads (17%) | called by muse, mutect2, varscan2
- P4HA3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PAN3 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCF11 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2
- PDZD7 | c.2076G>T p.R692S | Missense Mutation (SNP) | VAF 79/632 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PEG3 | c.482-6G>T | Splice Region (SNP) | VAF 28/272 reads (10%) | called by muse, mutect2
- PGLYRP2 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PHC1 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PHLDA1 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 74/378 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, varscan2
- PINLYP | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PLAUR | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 102/522 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PPEF1 | c.1311C>A p.Y437* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- PPFIA2 | c.846T>A p.Y282* | Nonsense Mutation (SNP) | VAF 29/317 reads (9%) | called by muse, mutect2
- PRDM9 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 102/459 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PRKAR2B | c.918+1G>C p.X306_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- PRKD1 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTPRF | c.4162G>T p.D1388Y | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTX3 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 82/604 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- QRICH1 | c.1746T>G p.H582Q | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAI14 | c.2860G>T p.V954L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2
- RAP1B | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RFPL2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RFPL4A | c.322T>G p.Y108D | Missense Mutation (SNP) | VAF 88/1160 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- RFPL4AL1 | c.322T>G p.Y108D | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, varscan2
- RIMS2 | c.4661G>C p.G1554A (on ENST00000666250 / NM_001348490.2; = p.G1125A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/429 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCART1 | c.2411C>A p.A804E | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- SERPINA3 | c.918-2A>G p.X306_splice | Splice Site (SNP) | VAF 90/509 reads (18%) | called by muse, mutect2, varscan2
- SERPINB1 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2
- SHISA9 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 114/682 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A13 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.349); called by muse, mutect2
- SLC4A4 | c.1649A>G p.Y550C (on ENST00000264485 / NM_001098484.3; = p.Y506C on NM_003759.4) | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- STAM | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- STK31 | c.893A>C p.E298A | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STK32A | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SV2B | c.1097G>T p.R366I | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SYNE1 | c.3904G>T p.G1302* (on ENST00000367255 / NM_182961.4; = p.G1309* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 112/521 reads (21%) | called by muse, mutect2, varscan2
- SYNE2 | c.7559G>T p.C2520F | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TAF3 | c.653C>A p.S218* | Nonsense Mutation (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- TAF3 | c.2455G>T p.A819S | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TBX18 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEP1 | c.6715G>T p.G2239C | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7B | c.4208C>G p.S1403* (on ENST00000272643; = p.S1401* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- TLR2 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- TMEM145 | c.420+2T>A p.X140_splice | Splice Site (SNP) | VAF 54/362 reads (15%) | called by muse, mutect2, varscan2
- TPH2 | c.1299G>A p.R433= | Splice Region (SNP) | VAF 35/283 reads (12%) | called by muse, mutect2, varscan2
- TRABD2B | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- TRBV23-1 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TRIM49C | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 57/417 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TSPEAR | c.1900A>G p.T634A | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TULP4 | c.1953C>A p.D651E | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBA5 | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- USH2A | c.13007G>T p.C4336F | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCAN | c.7466T>A p.L2489Q | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- VPS11 | c.949C>T p.L317F (on ENST00000620429; = p.L861F on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/556 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13D | c.8147T>G p.I2716S | Missense Mutation (SNP) | VAF 107/394 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VPS37C | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); called by muse, mutect2
- VPS41 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WASHC4 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR7 | c.2349C>A p.S783R | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.044); called by muse, mutect2
- ZMIZ1 | c.1604A>T p.D535V | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF233 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF292 | c.5157A>T p.L1719F | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF329 | c.706T>G p.C236G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ZNF384 | c.1427C>G p.A476G (on ENST00000361959; = p.A415G on NM_133476.5) | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.208); called by muse, varscan2
- ZNF385B | c.163A>C p.N55H | Missense Mutation (SNP) | VAF 94/473 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF429 | c.1939G>T p.V647L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.076); called by muse, mutect2
- ZNF491 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF628 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF724 | c.710A>T p.K237M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZSWIM6 | c.3367G>T p.G1123W | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACSM5 | c.489C>A p.A163= | Silent (SNP) | VAF 91/657 reads (14%) | catalogued as COSV59369265; called by muse, mutect2, varscan2
- AGTR1 | c.570C>A p.T190= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV62559125; called by muse, mutect2, varscan2
- ALCAM | c.60C>T p.T20= | Silent (SNP) | VAF 33/314 reads (11%) | catalogued as rs148340016; called by muse, mutect2
- ARHGAP9 | c.1081C>A p.R361= | Silent (SNP) | VAF 49/271 reads (18%) | called by muse, mutect2, varscan2
- ATP11C | c.3012A>T p.T1004= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- B3GAT2 | c.9C>G p.S3= | Silent (SNP) | VAF 75/352 reads (21%) | called by muse, mutect2, varscan2
- C17orf50 | c.399C>T p.G133= | Silent (SNP) | VAF 48/251 reads (19%) | called by muse, mutect2, varscan2
- C6 | c.1591C>A p.R531= | Silent (SNP) | VAF 130/546 reads (24%) | catalogued as COSV54712863; called by muse, mutect2, varscan2
- CCNA1 | c.1074C>T p.C358= | Silent (SNP) | VAF 60/301 reads (20%) | catalogued as rs780183027, COSV55223060; called by muse, mutect2, varscan2
- CELA3B | c.432C>T p.L144= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs1398967512; called by muse, mutect2
- CFHR5 | c.579G>T p.G193= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV56820870; called by muse, mutect2, varscan2
- COL2A1 | c.1029C>A p.A343= | Silent (SNP) | VAF 69/451 reads (15%) | called by muse, mutect2, varscan2
- CPQ | c.1077G>T p.L359= | Silent (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- CPS1 | c.3243G>A p.L1081= | Silent (SNP) | VAF 43/389 reads (11%) | catalogued as COSV51811179; called by muse, mutect2, varscan2
- CRX | c.657C>T p.D219= | Silent (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- DPP6 | c.1308A>G p.E436= (on ENST00000377770 / NM_001364500.2; = p.E374= on NM_001936.5) | Silent (SNP) | VAF 40/219 reads (18%) | catalogued as COSV59646471; called by muse, mutect2, varscan2
- DSCAM | c.4929C>T p.T1643= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as rs1315933749; called by muse, mutect2, varscan2
- EPHB2 | c.2724G>C p.T908= (on ENST00000400191 / NM_001309193.2; = p.T909= on NM_004442.7) | Silent (SNP) | VAF 74/269 reads (28%) | catalogued as COSV65861680; called by muse, mutect2, varscan2
- FAM47B | c.744C>G p.R248= | Silent (SNP) | VAF 64/200 reads (32%) | catalogued as rs369604412, COSV61454690; called by muse, varscan2
- FOXD3 | c.462C>T p.I154= | Silent (SNP) | VAF 73/497 reads (15%) | catalogued as rs1156880899; called by muse, mutect2, varscan2
- FRMPD2 | c.510C>A p.A170= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- GNAS | c.342G>A p.V114= | Silent (SNP) | VAF 118/1050 reads (11%) | catalogued as rs375410323; called by muse, mutect2, varscan2
- HTR1A | c.837C>T p.G279= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as rs201463384; called by muse, mutect2, varscan2
- IFIH1 | c.2496G>T p.L832= | Silent (SNP) | VAF 18/258 reads (7%) | catalogued as COSV99718744; called by muse, mutect2
- IGHG3 | c.213G>A p.V71= | Silent (SNP) | VAF 189/695 reads (27%) | called by muse, mutect2, varscan2
- KCNAB1 | c.135C>T p.S45= | Silent (SNP) | VAF 157/897 reads (18%) | catalogued as rs759145411; called by muse, mutect2, varscan2
- KIF16B | c.636A>T p.A212= | Silent (SNP) | VAF 74/352 reads (21%) | catalogued as COSV61709289; called by muse, mutect2, varscan2
- KIF7 | c.2517G>A p.Q839= | Silent (SNP) | VAF 29/386 reads (8%) | called by muse, mutect2
- LEFTY2 | c.882G>C p.V294= | Silent (SNP) | VAF 57/219 reads (26%) | called by muse, mutect2, varscan2
- LILRA2 | c.1386C>A p.V462= (on ENST00000391738 / NM_001130917.3; = p.V445= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/330 reads (14%) | called by muse, mutect2, varscan2
- LRBA | c.3984A>T p.T1328= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- LRRC43 | c.1242G>C p.L414= | Silent (SNP) | VAF 18/483 reads (4%) | called by muse, mutect2
- LRRC6 | c.1254A>G p.V418= | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1323C>A p.I441= | Silent (SNP) | VAF 38/277 reads (14%) | catalogued as COSV54438574, COSV54442536; called by muse, mutect2, varscan2
- MAGI2 | c.411G>T p.T137= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV100835566; called by muse, mutect2, varscan2
- MAPRE2 | c.105C>A p.R35= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as rs1447384209; called by muse, mutect2
- MATN2 | c.1767G>T p.T589= | Silent (SNP) | VAF 115/287 reads (40%) | called by muse, mutect2, varscan2
- MMP3 | c.225G>T p.V75= | Silent (SNP) | VAF 60/453 reads (13%) | called by muse, mutect2, varscan2
- NAGS | c.756G>T p.S252= | Silent (SNP) | VAF 64/459 reads (14%) | catalogued as COSV99517790; called by muse, mutect2, varscan2
- NAPSA | c.315G>A p.P105= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs367651287; called by muse, mutect2, varscan2
- OR52A1 | c.642C>A p.L214= | Silent (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- OR5F1 | c.561C>G p.L187= | Silent (SNP) | VAF 50/218 reads (23%) | catalogued as rs1197689940, COSV53546319; called by muse, mutect2, varscan2
- OR6M1 | c.594C>T p.L198= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- OR8B2 | c.609G>T p.V203= | Silent (SNP) | VAF 12/225 reads (5%) | catalogued as COSV100899415; called by muse, mutect2
- PARD3B | c.1329A>C p.G443= | Silent (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- PCDH1 | c.2298G>A p.Q766= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- PCDHA6 | c.1611G>C p.A537= | Silent (SNP) | VAF 146/1224 reads (12%) | catalogued as COSV65344249; called by muse, mutect2, varscan2
- PCDHGA7 | c.1530C>T p.D510= | Silent (SNP) | VAF 54/250 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.1977G>C p.T659= | Silent (SNP) | VAF 71/258 reads (28%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.654C>A p.G218= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- PDE10A | c.1044G>T p.G348= | Silent (SNP) | VAF 11/271 reads (4%) | called by muse, mutect2
- PDHA2 | c.213C>G p.R71= | Silent (SNP) | VAF 67/246 reads (27%) | catalogued as COSV54778172; called by muse, mutect2, varscan2
- PKNOX2 | c.135C>T p.I45= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as COSV100021370; called by muse, mutect2, varscan2
- PLXNB2 | c.4530A>G p.P1510= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as rs1462149535; called by muse, mutect2
- PPP1R17 | c.99G>A p.Q33= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs1562697793; called by muse, varscan2
- PTPRC | c.1140C>T p.N380= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs200643724; ClinVar: likely benign; called by muse, mutect2, varscan2
- RELN | c.5964G>A p.G1988= | Silent (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2
- RTP2 | c.258G>C p.S86= | Silent (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- S100A1 | c.36C>G p.L12= | Silent (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- SIX5 | c.1947G>T p.A649= | Silent (SNP) | VAF 81/415 reads (20%) | catalogued as rs751459007, COSV52178768; called by muse, mutect2, varscan2
- SLC26A3 | c.1149A>T p.I383= | Silent (SNP) | VAF 48/586 reads (8%) | catalogued as CD112527; called by muse, mutect2
- SLC8A1 | c.1173C>G p.V391= | Silent (SNP) | VAF 67/231 reads (29%) | called by muse, mutect2, varscan2
- SLC9A9 | c.582G>T p.L194= | Silent (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- SOX5 | c.1740C>T p.D580= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs1376642001, COSV100506038; called by muse, mutect2, varscan2
- ST8SIA1 | c.948A>G p.L316= | Silent (SNP) | VAF 61/302 reads (20%) | called by muse, mutect2, varscan2
- STAB2 | c.6621C>G p.G2207= | Silent (SNP) | VAF 80/331 reads (24%) | called by muse, mutect2, varscan2
- STK32C | c.1041G>A p.V347= | Silent (SNP) | VAF 42/278 reads (15%) | called by muse, mutect2, varscan2
- SYNJ1 | c.1659T>A p.S553= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2
- TEAD2 | c.1074G>T p.V358= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- TLNRD1 | c.531G>T p.P177= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV51256364; called by muse, mutect2, varscan2
- TNR | c.660C>T p.I220= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- TRIM41 | c.486A>G p.E162= | Silent (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- TRIM56 | c.2010G>A p.E670= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- TRPM6 | c.5421T>C p.L1807= | Silent (SNP) | VAF 34/462 reads (7%) | called by muse, mutect2
- TULP4 | c.1131G>T p.L377= | Silent (SNP) | VAF 33/402 reads (8%) | called by muse, mutect2
- UCK2 | c.456G>A p.K152= | Silent (SNP) | VAF 13/264 reads (5%) | catalogued as COSV63315045; called by muse, mutect2
- WRN | c.3243T>C p.T1081= | Silent (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- ZIC4 | c.249G>T p.A83= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as rs1472640858; called by muse, mutect2, varscan2
- AMPH | c.1182+1213G>T | Intron (SNP) | VAF 41/188 reads (22%) | called by muse, mutect2, varscan2
- APMAP | c.1042-371C>T | Intron (SNP) | VAF 34/379 reads (9%) | called by muse, mutect2
- APMAP | c.1042-372G>T | Intron (SNP) | VAF 31/374 reads (8%) | catalogued as COSV54173390; called by muse, mutect2
- BAX | c.474+23A>T | Intron (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- CLCN7 | c.141+642C>T | Intron (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- COL25A1 | c.1657-1926C>G | Intron (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- DCHS2 | n.5441G>C | RNA (SNP) | VAF 7/142 reads (5%) | catalogued as COSV100601744, COSV61776874; called by muse, mutect2
- DMAC2 | chr19:41440041 A>T | 5'Flank (SNP) | VAF 28/438 reads (6%) | called by muse, mutect2
- DPYD | c.762+43A>G | Intron (SNP) | VAF 14/121 reads (12%) | catalogued as COSV64597841; called by muse, varscan2
- EYS | c.1767-6659C>G | Intron (SNP) | VAF 28/848 reads (3%) | called by muse, mutect2
- F13A1 | c.1113-9237C>G | Intron (SNP) | VAF 54/281 reads (19%) | called by muse, mutect2, varscan2
- FAM78B | c.263+11197G>T | Intron (SNP) | VAF 19/288 reads (7%) | called by muse, mutect2
- GABRA3 | c.-26-27664G>T | Intron (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- GCNT2 | c.1018+27G>C | Intron (SNP) | VAF 92/548 reads (17%) | called by muse, mutect2, varscan2
- GRIA4 | c.2544+32C>A | Intron (SNP) | VAF 72/417 reads (17%) | called by muse, mutect2, varscan2
- LENG8 | c.*2819C>G | 3'UTR (SNP) | VAF 73/420 reads (17%) | called by muse, mutect2, varscan2
- LIM2 | c.175+30G>A | Intron (SNP) | VAF 83/451 reads (18%) | catalogued as rs376861251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINC00602 | n.1046C>A | RNA (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- LINC02740 | n.247C>A | RNA (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- MPDU1 | chr17:7583745 G>T | 5'Flank (SNP) | VAF 134/336 reads (40%) | called by muse, mutect2, varscan2
- MRGPRG | chr11:3221834 C>G | 5'Flank (SNP) | VAF 29/338 reads (9%) | called by muse, mutect2
- MUC19 | chr12:40545381 C>G | 3'Flank (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- NCAM1 | c.2457-1576C>T | Intron (SNP) | VAF 17/124 reads (14%) | catalogued as rs1555125990; called by muse, mutect2, varscan2
- NPR3 | c.*3256G>T | 3'UTR (SNP) | VAF 14/190 reads (7%) | catalogued as COSV54089039, COSV99422568; called by muse, mutect2
- NRXN1 | c.772+1056G>T | Intron (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-38547T>A | Intron (SNP) | VAF 105/247 reads (43%) | called by muse, mutect2, varscan2
- NUP160 | c.1102-4990G>C | Intron (SNP) | VAF 39/279 reads (14%) | called by muse, mutect2, varscan2
- QKI | c.934+995G>C | Intron (SNP) | VAF 32/114 reads (28%) | catalogued as rs1196728315; called by muse, mutect2, varscan2
- RPS9 | c.407+87G>T | Intron (SNP) | VAF 68/470 reads (14%) | called by muse, mutect2, varscan2
- SGCZ | c.40-298546A>G | Intron (SNP) | VAF 10/219 reads (5%) | called by muse, mutect2
- SH3BP2 | c.*28G>A | 3'UTR (SNP) | VAF 8/94 reads (9%) | catalogued as rs1392357732; called by muse, mutect2
- SSPOP | n.11502G>A | RNA (SNP) | VAF 20/307 reads (7%) | called by muse, mutect2
- SUGCT | c.1089+2795G>T | Intron (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.444C>T | RNA (SNP) | VAF 169/638 reads (26%) | catalogued as rs776384894; called by muse, varscan2
- TGFB1 | c.713-37_713-36dup | Intron (INS) | VAF 76/478 reads (16%) | catalogued as rs760991789; called by mutect2, varscan2
- TLX2 | chr2:74514202 C>T | 5'Flank (SNP) | VAF 21/247 reads (9%) | called by muse, mutect2
- TRIM54 | c.513+201C>G | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- TTLL2 | c.47+2848C>G | Intron (SNP) | VAF 74/328 reads (23%) | called by muse, mutect2, varscan2
- UROD | chr1:45012204 G>C | 5'Flank (SNP) | VAF 42/335 reads (13%) | called by muse, mutect2, varscan2
- YKT6 | c.-1C>A | 5'UTR (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
